Somatic mutation profile of tumor specimen 0DU4VK from CCDI case PBCKRV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,830 days).
Specimen 0DU4VK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65b4192a-551c-41b0-9fc9-ffc6dd527b29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU4V4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d7c622a-afc5-4e56-b509-84b1fb67b906

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 81/460 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 147/351 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCD1 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 57/483 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1383386358, CM950039; called by muse, varscan2
- ADCY6 | c.3479A>G p.Y1160C | Missense Mutation (SNP) | VAF 137/1210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765207297; called by muse, mutect2, varscan2
- DCAF12L2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 98/778 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63583759; called by muse, mutect2, varscan2
- INTS1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 64/1230 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as rs749316844; called by muse, mutect2
- WNK2 | c.5128G>A p.V1710I (on ENST00000297954 / NM_001282394.1; = p.V1673I on NM_006648.3) | Missense Mutation (SNP) | VAF 188/418 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs140544829; called by muse, mutect2, varscan2
- ADAMTS15 | c.2499G>T p.E833D | Missense Mutation (SNP) | VAF 46/553 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- ASB9 | c.662T>A p.F221Y | Missense Mutation (SNP) | VAF 44/787 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2
- ITGB5 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 316/641 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MMP26 | c.641T>C p.L214S | Missense Mutation (SNP) | VAF 85/699 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFKL | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 239/753 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SZT2 | c.9206A>G p.Y3069C (on ENST00000634258 / NM_001365999.1; = p.Y3012C on NM_015284.4) | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAS2R7 | c.679A>C p.T227P | Missense Mutation (SNP) | VAF 23/856 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- VIRMA | c.4993G>A p.V1665M | Missense Mutation (SNP) | VAF 28/690 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2
- WNK2 | c.3899T>A p.V1300E | Missense Mutation (SNP) | VAF 80/726 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BCL6B | c.1119G>A p.T373= | Silent (SNP) | VAF 559/1276 reads (44%) | catalogued as rs761383355; called by muse, mutect2, varscan2
- DOT1L | c.861C>T p.I287= | Silent (SNP) | VAF 78/1312 reads (6%) | catalogued as rs371914714, COSV67108851; called by muse, mutect2
- DYRK3 | c.153C>T p.C51= | Silent (SNP) | VAF 70/746 reads (9%) | called by muse, mutect2
- PELP1 | c.948G>A p.S316= | Silent (SNP) | VAF 300/655 reads (46%) | catalogued as rs781244089, COSV52586316, COSV99343166; called by muse, mutect2, varscan2
- SSX1 | c.303C>T p.F101= | Silent (SNP) | VAF 294/580 reads (51%) | catalogued as rs1556935513, COSV100976406, COSV65356324; called by muse, mutect2, varscan2
- TTN | c.34522+518G>A | Intron (SNP) | VAF 150/753 reads (20%) | catalogued as rs763249375; called by muse, mutect2, varscan2
